Surgical pathology report (de-identified scan), TCGA case TCGA-XU-A92U, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-A92U-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

MRN:

DOB:

Gender:M

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Thymic gland and thymoma long stitch on left upper pole

ICD O-3
Thymoma, type B2,
malignant 8584/3
Site: Thymus C37.9
J2 4/2/14

DIAGNOSIS

1. Thymus gland

a) Malignant thymoma by virtue of focal microscopic extension beyond capsule into

immediately adjacent mediastinal connective tissue, 5.5 cm in maximum dimension.

See comment.

b) Involutional changes of native thymus gland consistent with patient's age

COMMENT

The tumor is classifiable as a Predominantly mixed (Lattes/Bernatz), Cortical type (Muller Hermelink), Type B2 ('99 WHO), tumor which by virtue of focal microscopic extension through the capsule into immediately adjacent mediastinal connective tissue is considered to be malignant. In addition, a few of the sections show the tumor in this mediastinal tissue to be in close proximity to the external margin of the specimen as indicated by prior AgNO3 application. Complete resection therefore cannot be confirmed.

ELECTRONICALLY VERIFIED BY:

GROSS DESCRIPTION

The specimen container labeled with the patient's name and as "thymic gland and thymoma long stitch on left upper pole", contains a thymic gland oriented with a stitch at the left upper pole and received in 10% buffered formalin. The specimen is painted with silver nitrate. The

[page 2 of 2]
Patient Name:

MRN:

DOB:

Gender:M

Ordering MD:

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

specimen measures 19 cm SI x 6 cm across (right to left) x 3.0 cm AP. Within the mid to inferior aspect, there is a firm lobular mass measuring 5.5 cm SI x 3.5 cm across x 2.2 cm AP. On cut surface it is multinodular, firm, homogenous tan no cut surface. The remaining thymic tissue is grossly unremarkable on cut surface. A piece of the tumor mass and a piece of normal thymic tissue are taken for tissue freezing. On the anterior surface of the mass there is a portion of smooth shiny membranous tissue ?pericardium.

1A-1G - sections of tumor with adjacent thymic tissue (1E-1G - include anterior surface with ?pericardium).

1H - inferior thymic tissue

1I - mid region thymic tissue

1J - left upper pole thymic tissue

1K - right upper pole thymic tissue.

Status: complete

Page: 2 of 2

Source: NCI Genomic Data Commons file 5b57df62-3519-4e1d-bd3b-31dbfad5d363 (TCGA-XU-A92U.511791C2-9899-4503-A77A-4C4B3874BEBD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).